Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8XK, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8XK-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: F
DOB: [REDACTED] Age: [REDACTED]
Physician(s): [REDACTED] M.D.
[REDACTED] M.D.

Service: [REDACTED]
Location: [REDACTED]
MRN: [REDACTED]
Hospital #: [REDACTED]
Patient Type: [REDACTED]

Received: [REDACTED]
Reported: [REDACTED]

DIAGNOSIS:

UTERUS, CERVIX, BIOPSY
- INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY TO POORLY DIFFERENTIATED

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

Report Electronically Reviewed and Signed Out By [REDACTED] M.D.

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

[REDACTED] M.D.

History:

The patient is a [REDACTED] year old woman with cervical and vaginal bleeding, suspected cervical cancer.

Specimen(s) Received:

CERVIX, CERVICAL BIOPSY

Gross Description

Received is a formalin-filled container labeled with the patient's name and "cervix biopsy." The specimen consists of a single tissue fragment measuring 0.8 x 0.5 x 0.3 cm with a shiny gray surface. Wrapped in tissue, stained with hematoxylin, labeled A1. Jar 0.

[REDACTED] M.D.

This Surgical Pathology report is available on-line on [REDACTED] and [REDACTED]

ICD O.3
Carcinoma, squamous cell NOS 8070/3
Site: Cervix NOS 053.9
11/17/14

Physician Copy [REDACTED]
END OF REPORT

Page 1 of 1

Source: NCI Genomic Data Commons file 6e493a15-98b8-4a7c-bca4-df8ec85c6808 (TCGA-C5-A8XK.1F6ED6D4-2EF5-4F87-8F4E-08CD7834A2E5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).